Somatic mutation profile of tumor specimen TCGA-91-6848-01A (aliquot TCGA-91-6848-01A-11D-1945-08) from TCGA case TCGA-91-6848, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 59.8 years (21,829 days).
Specimen TCGA-91-6848-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9159d8c-37b7-43fc-bb66-5ef1c17ef8ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-91-6848-11A (Solid Tissue Normal), aliquot TCGA-91-6848-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94863b6b-7cbe-4aa4-90a0-cb5a1fa25436

The open-access MAF lists 623 somatic variants for this specimen: 465 protein-altering or splice-affecting, 143 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 399, Silent 143, Nonsense Mutation 26, Frame Shift Del 16, Splice Site 14, Intron 6, Splice Region 4, In Frame Del 3, 3'UTR 3, 5'UTR 2, 5'Flank 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as rs371524413, CM984589, COSV52698013, COSV52700732, COSV52710835, COSV52891661; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A2M | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as COSV59393116; called by muse, mutect2, varscan2
- ABCB10 | c.1559G>T p.G520V | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV60624448; called by muse, mutect2, varscan2
- ACLY | c.2549A>T p.Q850L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV61253505; called by muse, mutect2
- ACOT9 | c.238C>G p.P80A | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV60539081; called by muse, mutect2, varscan2
- ACSF3 | c.978G>C p.R326S | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58082280; called by muse, mutect2, varscan2
- ACSM4 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68067349, COSV68069659; called by muse, mutect2, varscan2
- ADAMTS13 | c.1442C>G p.A481G | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV63023414; called by muse, mutect2, varscan2
- ADAMTS18 | c.947C>A p.T316K | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV51423830; called by muse, mutect2, varscan2
- ADCY9 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53582407; called by muse, mutect2, varscan2
- ADGRB1 | c.2412G>T p.R804S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV60103883; called by muse, mutect2, varscan2
- ADGRB1 | c.3958G>A p.V1320I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs745792187, COSV60095999; called by muse, mutect2, varscan2
- ADH1C | c.629T>C p.M210T | Missense Mutation (SNP) | VAF 47/343 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs755222271, COSV72463708; called by muse, mutect2, varscan2
- AFF2 | c.1473G>C p.E491D | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.182); catalogued as COSV54009503; called by muse, mutect2, varscan2
- AKT1S1 | c.539A>G p.Y180C (on ENST00000344175 / NM_001098633.4; = p.Y200C on NM_032375.5) | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59278325; called by muse, mutect2, varscan2
- ANK2 | c.6549G>A p.M2183I | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.013); catalogued as COSV52191833; called by muse, mutect2, varscan2
- ANK2 | c.9137G>A p.S3046N | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs748521267, COSV52191859; called by muse, mutect2, varscan2
- ANLN | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV104379682, COSV56073795; called by muse, mutect2, varscan2
- AOX1 | c.1390G>T p.G464* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV101022221; called by muse, mutect2, varscan2
- AOX1 | c.1391G>T p.G464V | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101022222; called by muse, mutect2, varscan2
- APBB1IP | c.1156-2A>G p.X386_splice | Splice Site (SNP) | VAF 43/111 reads (39%) | catalogued as COSV66136779; called by muse, mutect2, varscan2
- APLP2 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); catalogued as COSV53845080; called by muse, mutect2, varscan2
- APOB | c.4636T>C p.S1546P | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51955149; called by muse, mutect2, varscan2
- APOBEC3A | c.470-1G>C p.X157_splice | Splice Site (SNP) | VAF 25/51 reads (49%) | catalogued as COSV50780015; called by muse, mutect2
- AQP12A | c.306G>T p.K102N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV100538980; called by muse, varscan2
- AQR | c.2434G>C p.A812P | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV50058036; called by mutect2, varscan2
- AR | c.76C>A p.L26M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65964504; called by muse, varscan2
- ARFGAP3 | c.1384T>C p.F462L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs1322101463, COSV54314839; called by muse, mutect2, varscan2
- ARHGAP27 | c.1933G>A p.D645N (on ENST00000428638 / NM_001282290.1; = p.D304N on NM_199282.3) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV65358853; called by mutect2, varscan2
- ARHGAP35 | c.1805T>C p.I602T | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV68336125; called by muse, mutect2, varscan2
- ARHGEF10L | c.2145G>T p.R715S | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51441390, COSV51441780; called by muse, mutect2, varscan2
- ARID2 | c.4558G>T p.E1520* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV57594762, COSV57615913; called by muse, mutect2, varscan2
- ARPP21 | c.1316C>G p.A439G | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV51809443; called by muse, mutect2, varscan2
- ASB17 | c.134C>A p.P45Q | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs778322729, COSV52412317; called by muse, mutect2, varscan2
- ATP10A | c.3946A>T p.R1316W | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV63525638; called by muse, mutect2, varscan2
- ATP10A | c.1788G>T p.R596S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV100791506; called by muse, mutect2, varscan2
- ATP10A | c.1787G>A p.R596K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.93); PolyPhen benign (0.173); catalogued as COSV100791507, COSV100791573; called by muse, mutect2, varscan2
- ATP6V1G2 | c.128A>G p.E43G | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV58215261; called by muse, mutect2
- BABAM2 | c.852-1G>C p.X284_splice | Splice Site (SNP) | VAF 17/61 reads (28%) | catalogued as COSV59629210, COSV59633893; called by muse, mutect2, varscan2
- BCL9L | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.425); catalogued as COSV52689652; called by muse, mutect2, varscan2
- BICC1 | c.692T>A p.I231K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV54067351; called by muse, mutect2, varscan2
- BMT2 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.549); catalogued as COSV51781474; called by muse, mutect2, varscan2
- BRCA2 | c.7507G>T p.V2503F | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV66451402, COSV66463407; called by muse, mutect2
- C10orf53 | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777917968, COSV65108182; called by muse, mutect2, varscan2
- C11orf65 | c.142C>A p.R48S | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.242); catalogued as COSV67598821; called by muse, mutect2, varscan2
- C18orf54 | c.80G>T p.S27I | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.568); catalogued as COSV55619683; called by muse, mutect2, varscan2
- C8B | c.1156G>C p.G386R | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.238); catalogued as COSV64779910; called by muse, mutect2, varscan2
- C8B | c.195T>G p.C65W | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64779915; called by muse, mutect2, varscan2
- CAPSL | c.445C>G p.Q149E | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as COSV68439612; called by muse, mutect2
- CASR | c.2981T>A p.V994D (on ENST00000490131; = p.V1071D on NM_000388.4) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as COSV56141861; called by muse, mutect2, varscan2
- CC2D2A | c.3101A>G p.Q1034R | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67505881; called by muse, mutect2
- CCDC14 | c.2552A>T p.Q851L (on ENST00000488653; = p.Q803L on NM_022757.5) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV59948227; called by muse, mutect2, varscan2
- CCDC70 | c.560T>C p.F187S | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV54431108; called by muse, mutect2
- CCNF | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as rs777880085, COSV53543639; called by muse, mutect2, varscan2
- CCR6 | c.127C>A p.Q43K | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV59476370; called by muse, mutect2, varscan2
- CCR8 | c.463C>A p.L155M | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.823); catalogued as COSV58338099; called by muse, mutect2, varscan2
- CD2AP | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV63763349; called by muse, mutect2, varscan2
- CD82 | c.466T>C p.Y156H | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV57037716; called by muse, mutect2, varscan2
- CDH10 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100053014, COSV52588323; called by muse, mutect2, varscan2
- CDH2 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52298008, COSV99296788; called by muse, mutect2, varscan2
- CDK13 | c.2551A>T p.I851L | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.429); catalogued as COSV51707090; called by muse, mutect2, varscan2
- CDK16 | c.1323G>T p.M441I | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV52093622; called by muse, mutect2, varscan2
- CEMIP2 | c.1847C>T p.T616I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs745705327, COSV65489885; called by muse, mutect2, varscan2
- CENPF | c.7924G>T p.E2642* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV65279609; called by muse, mutect2, varscan2
- CFH | c.612G>T p.K204N | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100661624; called by muse, mutect2, varscan2
- CHI3L1 | c.636G>C p.W212C | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55140360; called by muse, mutect2, varscan2
- CHMP4C | c.312G>T p.E104D | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV51929140; called by mutect2, varscan2
- CHRM2 | c.278C>A p.P93H | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100280895, COSV57785775; called by muse, mutect2, varscan2
- CHRNA7 | c.1149C>A p.N383K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV100181725; called by mutect2, varscan2
- CHRNB2 | c.1049A>T p.Q350L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV63809572; called by muse, mutect2
- CLCN6 | c.88-1G>C p.X30_splice | Splice Site (SNP) | VAF 6/41 reads (15%) | catalogued as COSV56743505; called by muse, mutect2
- CMKLR1 | c.707T>G p.I236S (on ENST00000312143 / NM_001142344.2; = p.I234S on NM_004072.3) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56442318; called by muse, mutect2, varscan2
- CNGA3 | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs143531659; called by muse, mutect2, varscan2
- CNN1 | c.82C>G p.H28D | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV99372520; called by muse, mutect2, varscan2
- CNTN1 | c.877G>T p.A293S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.817); catalogued as COSV61646291; called by muse, mutect2, varscan2
- COL12A1 | c.2050A>T p.T684S | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.65); catalogued as COSV59409480; called by muse, mutect2, varscan2
- COL20A1 | c.347T>A p.L116Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58928549; called by muse, mutect2, varscan2
- COL22A1 | c.3664-1G>A p.X1222_splice | Splice Site (SNP) | VAF 14/72 reads (19%) | catalogued as rs745780915, COSV100280021, COSV57363236; called by muse, mutect2, varscan2
- COL3A1 | c.2788G>A p.G930R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58597571; called by muse, mutect2, varscan2
- COL6A3 | c.9064C>A p.L3022I | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV55112697; called by muse, mutect2, varscan2
- COQ10A | c.269G>C p.R90P | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV57523872, COSV57526065; called by muse, mutect2, varscan2
- CPA6 | c.691T>C p.Y231H | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.611); catalogued as COSV52743917; called by muse, mutect2, varscan2
- CPAMD8 | c.1540G>T p.G514W (on ENST00000651564; = p.G467W on NM_015692.5) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52240810; called by muse, mutect2, varscan2
- CPB2 | c.262G>T p.G88* | Nonsense Mutation (SNP) | VAF 43/119 reads (36%) | catalogued as rs543856991, COSV51675960, COSV51677748; called by muse, mutect2, varscan2
- CPXM1 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV66046915; called by muse, mutect2, varscan2
- CREM | c.619A>G p.T207A (on ENST00000429130; = p.T174A on NM_181571.3) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV59770328; called by muse, mutect2, varscan2
- CRYGS | c.289C>G p.Q97E | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV100329933, COSV57193079; called by muse, mutect2, varscan2
- CSMD3 | c.10640G>T p.S3547I (on ENST00000297405 / NM_001363185.1; = p.S3378I on NM_052900.3) | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV52116090; called by muse, mutect2, varscan2
- CSMD3 | c.6524G>T p.S2175I (on ENST00000297405 / NM_001363185.1; = p.S2071I on NM_052900.3) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV52334834; called by muse, varscan2
- CSN2 | c.64C>A p.L22I | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV61992814; called by muse, varscan2
- CUL3 | c.383G>C p.R128P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52366153, COSV52371279; called by muse, mutect2, varscan2
- CWC22 | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as COSV55432944; called by muse, varscan2
- CYP11B2 | c.1200G>A p.G400= | Splice Region (SNP) | VAF 6/34 reads (18%) | catalogued as COSV59996245, COSV59996592, COSV59998090; called by muse, mutect2, varscan2
- CYP26B1 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.581); catalogued as rs752879483, COSV50015104; called by muse, mutect2, varscan2
- CYSLTR2 | c.420G>C p.M140I | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99935397; called by muse, mutect2, varscan2
- CYSLTR2 | c.421G>T p.V141F | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99935399; called by muse, varscan2
- DACH2 | c.1294C>G p.L432V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV64166715, COSV64187650; called by muse, mutect2, varscan2
- DARS2 | c.359G>C p.G120A | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53409487; called by muse, mutect2, varscan2
- DCHS1 | c.313C>A p.R105S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV55043644; called by muse, varscan2
- DDX55 | c.1400G>C p.R467T | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV53017884; called by muse, mutect2, varscan2
- DEFB110 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as rs145542651, COSV64485051; called by muse, mutect2, varscan2
- DENND1A | c.1844A>T p.D615V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65357278; called by muse, mutect2, varscan2
- DENND4B | c.1326G>T p.S442= | Splice Region (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100768798; called by muse, mutect2, varscan2
- DGKB | c.1393C>G p.P465A | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51805079, COSV51823120; called by muse, mutect2, varscan2
- DGUOK | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.708); catalogued as COSV51204770; called by muse, mutect2, varscan2
- DIS3L | c.622C>T p.Q208* (on ENST00000319212 / NM_001143688.3; = p.Q125* on NM_133375.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 22/83 reads (27%) | catalogued as rs1381696599, COSV59914565; called by muse, mutect2, varscan2
- DLK1 | c.998G>A p.W333* | Nonsense Mutation (SNP) | VAF 11/59 reads (19%) | catalogued as COSV57993640; called by muse, mutect2, varscan2
- DNAH1 | c.10335G>C p.E3445D | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as COSV70237228; called by muse, mutect2
- DNAH17 | c.9770A>T p.D3257V | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.543); catalogued as COSV67761915; called by muse, mutect2, varscan2
- DNAH8 | c.8602G>A p.A2868T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.038); catalogued as COSV59484024; called by muse, mutect2, varscan2
- DNAJA1 | c.701T>A p.L234Q | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV58311703; called by muse, mutect2, varscan2
- DNAJC1 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1278990860, COSV65376920; called by muse, varscan2
- DOCK2 | c.1655T>G p.L552R | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV56991381; called by muse, mutect2, varscan2
- DOK6 | c.322T>A p.C108S | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV66938327; called by muse, mutect2, varscan2
- DOP1A | c.4910A>C p.Q1637P | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52719185; called by muse, mutect2, varscan2
- DSTYK | c.2530G>T p.G844C | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65688680; called by muse, mutect2, varscan2
- DUOXA2 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV50995031; called by muse, mutect2, varscan2
- DUSP12 | c.228G>A p.W76* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | catalogued as COSV63411727; called by muse, mutect2, varscan2
- DUSP15 | c.422A>C p.Q141P (on ENST00000278979 / NM_001320479.1; = p.Q144P on NM_080611.4) | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs777546001, COSV54068660; called by muse, mutect2, varscan2
- DXO | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV61715262; called by muse, mutect2, varscan2
- ENPEP | c.592G>A p.G198S | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.672); catalogued as rs765114745, COSV54458251; called by muse, mutect2, varscan2
- EPHA10 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57621410, COSV57627613; called by muse, mutect2, varscan2
- ERC2 | c.1358T>C p.L453S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV55668070; called by mutect2, varscan2
- EWSR1 | c.1909G>A p.G637R | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.042); catalogued as COSV58428202; called by muse, mutect2, varscan2
- EYS | c.400C>A p.H134N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.157); catalogued as rs765304266, COSV61001356; called by muse, mutect2, varscan2
- FAM126A | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV69017745; called by muse, mutect2, varscan2
- FAM47C | c.938C>G p.S313* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV63730872; called by muse, mutect2, varscan2
- FARP1 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60333653; called by muse, mutect2, varscan2
- FATE1 | c.303C>A p.Y101* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV100948142, COSV64849384; called by muse, mutect2, varscan2
- FBN2 | c.3509G>T p.R1170M | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52529320; called by muse, mutect2, varscan2
- FBN2 | c.2081G>T p.G694V | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52547770; called by muse, mutect2, varscan2
- FBXO47 | c.1147G>C p.V383L | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV65242391, COSV65242982; called by muse, mutect2, varscan2
- FGF3 | c.511del p.R171Afs*152 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as COSV61926261; called by mutect2, pindel, varscan2
- FGGY | c.781G>C p.A261P | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58046958; called by muse, mutect2, varscan2
- FGGY | c.1222-1G>C p.X408_splice | Splice Site (SNP) | VAF 28/96 reads (29%) | catalogued as COSV58046981; called by muse, mutect2, varscan2
- FILIP1 | c.3460C>G p.R1154G | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52741820; called by muse, mutect2, varscan2
- FIP1L1 | c.523T>A p.Y175N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61000104; called by muse, mutect2, varscan2
- FKBP9 | c.1193C>A p.A398D | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV54235333; called by muse, mutect2, varscan2
- FLG | c.9580C>A p.H3194N | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV64250932; called by mutect2, varscan2
- FNBP1 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV63091196; called by muse, mutect2
- FREM2 | c.5581G>T p.V1861L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.884); catalogued as COSV54854389, COSV54855129; called by mutect2, varscan2
- FSCB | c.1621G>T p.E541* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV61219721; called by muse, mutect2, varscan2
- GABRB3 | c.1382C>G p.S461C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV54675582, COSV54685992; called by muse, varscan2
- GABRB3 | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV54686021; called by muse, mutect2, varscan2
- GALNT3 | c.325C>G p.P109A | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV67062597; called by muse, mutect2, varscan2
- GALNTL6 | c.1281C>A p.C427* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV72494379; called by muse, mutect2, varscan2
- GCDH | c.131C>G p.S44W | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); catalogued as rs201970551, COSV53436134; called by muse, mutect2, varscan2
- GHR | c.1091G>T p.R364I | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50118034, COSV50134231; called by muse, mutect2, varscan2
- GHRH | c.198C>G p.N66K | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.436); catalogued as rs759618578, COSV52902313, COSV52903236; called by muse, mutect2, varscan2
- GLDC | c.2711T>C p.M904T | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58685994; called by muse, mutect2
- GNMT | c.714G>C p.L238F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV55105862; called by muse, mutect2, varscan2
- GOLGA4 | c.5992A>T p.M1998L | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV100729149; called by muse, mutect2, varscan2
- GPRASP1 | c.2546A>G p.E849G | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV100851072; called by muse, mutect2
- GPRIN3 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs1420149065, COSV60886621; called by muse, varscan2
- GRAMD2A | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59035733; called by muse, mutect2, varscan2
- GRID2 | c.457C>A p.H153N | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56274515; called by muse, mutect2, varscan2
- GRIK1 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV58733943; called by muse, mutect2, varscan2
- GRIK3 | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66147761; called by muse, mutect2, varscan2
- GRM6 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV51450358; called by muse, mutect2, varscan2
- GUCY1A1 | c.932G>T p.R311M | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV56656413, COSV99638619; called by muse, mutect2, varscan2
- GUCY1A1 | c.933G>T p.R311S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV99638623, COSV99638725; called by muse, mutect2, varscan2
- H1-8 | c.896C>A p.A299D | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); catalogued as COSV60719963; called by muse, mutect2, varscan2
- H3C11 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV100137683, COSV58899983; called by muse, mutect2, varscan2
- HECW1 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.003); catalogued as COSV101224246; called by muse, mutect2, varscan2
- HELB | c.2683C>G p.Q895E | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV56076499; called by muse, mutect2
- HLX | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV65045766; called by muse, mutect2, varscan2
- HMCN1 | c.16324T>A p.C5442S | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV54945746; called by muse, mutect2
- HMSD | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.679); catalogued as COSV68817164; called by muse, mutect2, varscan2
- HNF4A | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.038); catalogued as rs760038979, COSV57389703; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HROB | c.143G>T p.R48M | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV55371088; called by muse, mutect2, varscan2
- HSPA1L | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65149537; called by muse, varscan2
- HSPA2 | c.683A>T p.D228V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV55971391; called by muse, mutect2, varscan2
- HTR3A | c.159G>C p.R53S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.3); catalogued as COSV55471904; called by muse, mutect2, varscan2
- HTRA2 | c.379G>T p.G127C | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV51215715; called by muse, mutect2, varscan2
- IBTK | c.1790G>C p.G597A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV60396564; called by muse, mutect2, varscan2
- IDO2 | c.305A>T p.Q102L (on ENST00000389060; = p.Q115L on NM_194294.2) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV58430085; called by muse, mutect2, varscan2
- IGHV3-72 | c.250T>A p.S84T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); catalogued as COSV70409800; called by muse, mutect2, varscan2
- IGKV2D-24 | c.131G>T p.R44M | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs769748347; called by muse, mutect2, varscan2
- IL16 | c.2726C>A p.P909H (on ENST00000302987 / NM_172217.5; = p.P208H on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as COSV57268837; called by muse, mutect2, varscan2
- IL1RL1 | c.351G>C p.L117F | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as rs780029595, COSV52121042; called by muse, mutect2, varscan2
- INSL6 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1457206008, COSV101068546, COSV67563566; called by muse, mutect2, varscan2
- INTS1 | c.4694C>G p.S1565C | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV67180048; called by muse, mutect2, varscan2
- IRAK1 | c.1979T>C p.I660T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64113767; called by muse, mutect2, varscan2
- IRF2BP2 | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV64015747; called by muse, mutect2
- ITGA8 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV65234103, COSV65237050; called by muse, mutect2, varscan2
- ITGB8 | c.1149G>T p.K383N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV56015104; called by muse, mutect2, varscan2
- ITGBL1 | c.587-1G>T p.X196_splice | Splice Site (SNP) | VAF 18/74 reads (24%) | catalogued as COSV66012459; called by muse, mutect2, varscan2
- ITPR2 | c.1529G>C p.R510T | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67276961; called by muse, mutect2, varscan2
- JRKL | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV53595686; called by muse, mutect2, varscan2
- KCNB1 | c.2210C>A p.S737Y | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.825); catalogued as COSV65571183; called by muse, mutect2
- KCND2 | c.472G>T p.G158W | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV58606417; called by muse, mutect2, varscan2
- KCNG3 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60151208; called by muse, mutect2, varscan2
- KCNH1 | c.2863C>A p.L955I (on ENST00000271751 / NM_172362.3; = p.L928I on NM_002238.4) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.125); catalogued as COSV55107003; called by muse, mutect2, varscan2
- KCNJ3 | c.1283A>G p.Y428C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); catalogued as COSV54545655; called by muse, mutect2, varscan2
- KCNQ3 | c.2469del p.S824Rfs*4 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as COSV101196164; called by mutect2, pindel, varscan2
- KCNQ5 | c.2726G>T p.R909L | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100573017; called by muse, mutect2, varscan2
- KCNT2 | c.3067A>G p.R1023G | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.52); catalogued as rs1378187209, COSV54078429; called by muse, mutect2, varscan2
- KDR | c.429C>A p.N143K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.391); catalogued as COSV55777629, COSV99816632; called by muse, mutect2, varscan2
- KEAP1 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV50260398, COSV50261323, COSV50261936; called by muse, mutect2, varscan2
- KHDC4 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs773230849, COSV64165931; called by muse, mutect2, varscan2
- KIAA1210 | c.481G>T p.G161* | Nonsense Mutation (SNP) | VAF 9/13 reads (69%) | catalogued as COSV68180553; called by muse, mutect2
- KIF5A | c.2293G>T p.E765* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV54060081; called by muse, mutect2
- KLHDC3 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV55065852; called by muse, mutect2, varscan2
- KLHL1 | c.388G>T p.V130L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV100918104; called by muse, mutect2, varscan2
- KLKB1 | c.1044C>G p.F348L | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.039); catalogued as COSV52999848; called by muse, mutect2, varscan2
- LAMA3 | c.5496C>G p.D1832E (on ENST00000313654 / NM_198129.4; = p.D223E on NM_000227.6) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52544342; called by muse, mutect2
- LAMB4 | c.2293G>T p.G765W | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52732370; called by muse, mutect2, varscan2
- LCTL | c.1049C>A p.T350K | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.923); catalogued as COSV57183634; called by muse, mutect2, varscan2
- LONP1 | c.647T>G p.I216S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV62263494; called by muse, mutect2, varscan2
- LRP1 | c.2858G>T p.W953L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99677111; called by muse, varscan2
- LRP1 | c.2859G>T p.W953C | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99677115; called by muse, varscan2
- LRP2 | c.8910G>T p.W2970C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55577227; called by muse, mutect2, varscan2
- LRPPRC | c.2386G>T p.A796S | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV53243841; called by muse, mutect2
- LRRC32 | c.1377G>C p.R459S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1340784391, COSV99477281; called by muse, mutect2, varscan2
- LRRC32 | c.1376G>T p.R459M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as rs751664693, COSV99477284; called by muse, mutect2, varscan2
- LRRC56 | c.423G>A p.K141= | Splice Region (SNP) | VAF 10/63 reads (16%) | catalogued as COSV54248130; called by muse, mutect2, varscan2
- LRRC7 | c.677G>T p.R226I (on ENST00000651989 / NM_001370785.2; = p.R193I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV50610386, COSV99229563; called by muse, mutect2, varscan2
- LRRC7 | c.3893A>G p.E1298G (on ENST00000651989 / NM_001370785.2; = p.E1265G on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); catalogued as rs1371220914, COSV50645225; called by muse, mutect2, varscan2
- LRRFIP2 | c.2062A>G p.T688A | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as COSV51625157; called by muse, mutect2, varscan2
- LSS | c.44A>T p.K15M | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV62703009; called by muse, mutect2, varscan2
- LTA4H | c.803A>G p.Y268C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57384712; called by muse, mutect2, varscan2
- MACO1 | c.643G>T p.A215S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.79); PolyPhen benign (0.197); catalogued as COSV65478587; called by muse, mutect2, varscan2
- MAGEB10 | c.437A>T p.K146M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV63312824; called by muse, mutect2, varscan2
- MAGEC1 | c.2031G>T p.Q677H | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); catalogued as rs777289996, COSV53582409; called by muse, mutect2, varscan2
- MAGI1 | c.2659G>T p.G887C (on ENST00000402939 / NM_001033057.2; = p.G915C on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58347058; called by muse, mutect2, varscan2
- MAN1A2 | c.743G>C p.R248T | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV62982024; called by muse, mutect2
- MAN2A1 | c.750G>T p.W250C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54859317; called by muse, mutect2, varscan2
- MAP4K4 | c.2699C>T p.S900L (on ENST00000347699 / NM_001242559.2; = p.S818L on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as rs375209088; called by muse, mutect2, varscan2
- MAP7D3 | c.1715G>A p.C572Y | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as COSV60172804; called by muse, mutect2, varscan2
- MAPK1IP1L | c.314C>G p.P105R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67106878; called by muse, mutect2, varscan2
- MASP1 | c.2002T>C p.W668R | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61831254; called by muse, mutect2, varscan2
- MIB2 | c.1890G>T p.R630S | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.628); catalogued as rs1316660033, COSV61543538; called by muse, mutect2, varscan2
- MINDY4 | c.2234G>C p.G745A | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV54678823; called by muse, mutect2, varscan2
- MMP19 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs144373478, COSV59453505; called by muse, mutect2
- MRGPRX3 | c.969A>T p.*323Cext*20 | Nonstop Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV66934936; called by muse, mutect2, varscan2
- MTHFD1L | c.2828T>C p.I943T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66227816; called by muse, mutect2, varscan2
- MTUS2 | c.2111A>G p.Q704R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752381898, COSV70923650; called by muse, mutect2, varscan2
- MUC5B | c.5069C>T p.T1690I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV71595990; called by muse, mutect2, varscan2
- MUC5B | c.12953C>A p.S4318Y | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV101500730, COSV71594556; called by muse, mutect2, varscan2
- MYBPC2 | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as COSV63100371; called by muse, mutect2
- MYCBP2 | c.7771-1G>T p.X2591_splice (on ENST00000357337; = p.X2629_splice on NM_015057.5) | Splice Site (SNP) | VAF 12/146 reads (8%) | catalogued as COSV62041444; called by muse, mutect2
- MYLK | c.2090C>A p.A697D | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60623958; called by muse, mutect2, varscan2
- MYO18B | c.1140C>A p.S380R | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV59150493; called by muse, mutect2, varscan2
- MYO5A | c.2773A>C p.M925L | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV62565258; called by muse, mutect2, varscan2
- MYO5B | c.3824G>T p.R1275L | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV53232766, COSV53235776; called by muse, varscan2
- MYO5B | c.3036G>C p.E1012D | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs373812332; called by muse, mutect2, varscan2
- NAV3 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.04); catalogued as COSV57115151; called by muse, mutect2, varscan2
- NCBP1 | c.1216A>T p.N406Y | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV64317520; called by muse, mutect2, varscan2
- NCOA2 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71765071; called by muse, mutect2, varscan2
- NCOA7 | c.2080G>T p.A694S | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV57660883; called by muse, mutect2, varscan2
- NF2 | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1468744457, COSV58526074, COSV58531654; called by muse, mutect2, varscan2
- NFE2 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs755502802, COSV56457582; called by muse, mutect2, varscan2
- NKAIN2 | c.611T>C p.M204T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.482); catalogued as COSV63732561; called by muse, mutect2, varscan2
- NPAT | c.3472G>C p.E1158Q | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); catalogued as COSV53722258; called by muse, mutect2
- NPHP4 | c.2332G>T p.V778L | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV65398397; called by muse, mutect2, varscan2
- NR1H4 | c.665T>C p.L222P (on ENST00000551379 / NM_001206993.2; = p.L208P on NM_005123.4) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1042693689, COSV51849170; called by muse, mutect2, varscan2
- NUP214 | c.5695A>T p.N1899Y | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63913462; called by muse, mutect2, varscan2
- OPRL1 | c.986G>A p.C329Y | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61093136; called by muse, mutect2, varscan2
- OR13G1 | c.776C>A p.P259H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100687531; called by muse, mutect2, varscan2
- OR13G1 | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100687538; called by muse, mutect2, varscan2
- OR2A14 | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV68718470, COSV68718758; called by mutect2, varscan2
- OR2J3 | c.433C>T p.H145Y | Missense Mutation (SNP) | VAF 44/355 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1387038205, COSV65849766; called by muse, mutect2, varscan2
- OR2M5 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV63547150; called by muse, mutect2, varscan2
- OR2T12 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV58776706; called by muse, mutect2, varscan2
- OR4C46 | c.412G>T p.V138L | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.009); catalogued as COSV60221463; called by muse, mutect2, varscan2
- OR4C6 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.654); catalogued as rs746616835, COSV58603591, COSV58605102, COSV58606600; called by mutect2, varscan2
- OR4K17 | c.654C>G p.Y218* | Nonsense Mutation (SNP) | VAF 17/100 reads (17%) | catalogued as COSV59649237; called by muse, mutect2, varscan2
- OR51A7 | c.287C>A p.A96D | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV63788696, COSV63789054; called by muse, mutect2
- OR51F1 | c.523C>G p.L175V | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as COSV58581030; called by muse, mutect2, varscan2
- OR5I1 | c.882G>C p.L294F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV100041329, COSV100041775; called by mutect2, varscan2
- OR5J2 | c.347C>A p.S116* | Nonsense Mutation (SNP) | VAF 37/110 reads (34%) | catalogued as COSV56623507; called by muse, mutect2, varscan2
- OR6A2 | c.779G>C p.S260T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV60265982; called by muse, mutect2, varscan2
- OR6C76 | c.132C>G p.I44M | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); catalogued as COSV100093975, COSV60390193; called by muse, mutect2, varscan2
- OR6N1 | c.138C>A p.F46L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.234); catalogued as COSV58647345, COSV58650137; called by muse, mutect2, varscan2
- OR8G5 | c.871A>G p.S291G | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); catalogued as COSV100422648; called by muse, mutect2, varscan2
- OSGIN2 | c.100A>G p.M34V | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs1388992594, COSV52411834; called by muse, mutect2, varscan2
- PAPPA2 | c.4987G>C p.V1663L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV62813199; called by muse, mutect2, varscan2
- PARP8 | c.519-1G>T p.X173_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | catalogued as COSV55867623; called by muse, mutect2, varscan2
- PATL1 | c.2258G>C p.R753P | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV100275229; called by muse, mutect2
- PCDH11X | c.313C>G p.H105D | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.065); catalogued as COSV53509235; called by muse, mutect2, varscan2
- PCDHA2 | c.1572C>A p.D524E | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65371597; called by muse, mutect2
- PCDHA3 | c.1238T>G p.L413R | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63544421, COSV63546682; called by muse, mutect2, varscan2
- PCDHGA1 | c.1841C>A p.P614Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65300188; called by muse, mutect2, varscan2
- PCDHGA2 | c.1920G>T p.Q640H | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.35); catalogued as COSV54044205; called by mutect2, varscan2
- PCDHGC3 | c.1555G>C p.V519L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52771274; called by muse, mutect2, varscan2
- PCMTD1 | c.851G>A p.R284K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as COSV100859709, COSV62125405; called by muse, mutect2, varscan2
- PCNT | c.1489C>A p.R497S | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs371251124, COSV64033551; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDE1C | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.041); catalogued as COSV58530862; called by muse, mutect2, varscan2
- PDE3B | c.1226C>A p.P409H | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV56391468; called by muse, mutect2
- PEAR1 | c.2845C>A p.P949T | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV52776269; called by muse, varscan2
- PHF21B | c.326C>A p.P109H | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57562860; called by muse, mutect2, varscan2
- PHKA2 | c.2753G>A p.G918E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66056663; called by muse, mutect2, varscan2
- PKD1 | c.2825A>T p.E942V | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV51926875; called by muse, mutect2, varscan2
- PKDREJ | c.5203G>A p.D1735N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.07); catalogued as COSV53553625; called by muse, mutect2, varscan2
- PLAC8 | c.244-2A>G p.X82_splice | Splice Site (SNP) | VAF 12/39 reads (31%) | catalogued as COSV61047197, COSV61048368; called by muse, mutect2, varscan2
- PMS2 | c.494C>T p.T165I | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs587781541, COSV56224660; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POTEE | c.386T>C p.M129T | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.011); catalogued as rs534508775, COSV58246261; called by muse, mutect2, varscan2
- PPFIA2 | c.635C>G p.A212G | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV61047393, COSV61057652; called by muse, mutect2, varscan2
- PPIL4 | c.682G>T p.G228* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV53569019; called by muse, mutect2, varscan2
- PPP1R16B | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV55384947; called by muse, mutect2, varscan2
- PRAMEF4 | c.66C>A p.D22E | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.234); catalogued as rs191169219, COSV52441754, COSV99340030; called by muse, mutect2, varscan2
- PRB3 | c.499C>A p.P167T | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.427); catalogued as COSV54393709, COSV54393851; called by muse, varscan2
- PREX2 | c.3251G>C p.R1084P | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV55761842, COSV55802142; called by muse, mutect2, varscan2
- PRKCG | c.290C>G p.P97R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV54733877; called by muse, mutect2
- PSMB1 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.023); catalogued as COSV51532103; called by muse, mutect2
- PTPN13 | c.5974G>T p.V1992L (on ENST00000411767 / NM_080683.3; = p.V1973L on NM_006264.3) | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV57418679; called by muse, mutect2
- PTRHD1 | c.313C>G p.H105D | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV53232677; called by muse, mutect2
- PYGL | c.923T>C p.I308T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs953924552, COSV53589093; called by muse, mutect2, varscan2
- QARS1 | c.1978A>G p.S660G | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV60276287; called by muse, mutect2, varscan2
- RABGAP1L | c.1446G>T p.Q482H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); catalogued as COSV52332056; called by muse, mutect2, varscan2
- RASA3 | c.1092G>A p.Q364= | Splice Region (SNP) | VAF 12/48 reads (25%) | catalogued as rs1485124723, COSV61874311; called by muse, mutect2, varscan2
- RAVER2 | c.1315G>C p.E439Q (on ENST00000294428 / NM_001366165.1; = p.E426Q on NM_018211.4) | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV53811397; called by muse, mutect2, varscan2
- RBM10 | c.2342C>T p.S781L | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1556782040, COSV61308142, COSV61309495; called by muse, mutect2, varscan2
- RECQL4 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV52883068, COSV52883154; called by muse, mutect2, varscan2
- REEP1 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV51259934; called by muse, mutect2, varscan2
- RET | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60710147; called by mutect2, varscan2
- RHOBTB1 | c.1771G>T p.V591L | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV61960412; called by muse, mutect2, varscan2
- RIMS1 | c.227A>C p.Q76P | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV53487702; called by muse, mutect2, varscan2
- RIMS1 | c.3491G>A p.R1164K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.9); catalogued as COSV53487707, COSV99328652; called by muse, mutect2, varscan2
- ROR1 | c.565A>G p.M189V | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759045335, COSV64293829; called by muse, mutect2, varscan2
- RPE65 | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 19/37 reads (51%) | catalogued as COSV52018934; called by muse, mutect2, varscan2
- RPUSD4 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 61/240 reads (25%) | catalogued as COSV53598751; called by muse, mutect2, varscan2
- RRM1 | c.1973A>T p.Q658L | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV56166474; called by muse, mutect2, varscan2
- RRP12 | c.1810G>T p.A604S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.068); catalogued as COSV59671877; called by muse, mutect2, varscan2
- RXFP1 | c.1835C>A p.T612K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as COSV57046150, COSV57057489; called by muse, mutect2, varscan2
- RYR2 | c.676G>C p.G226R | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63703200, COSV63718046; called by muse, mutect2, varscan2
- RYR3 | c.9164C>A p.A3055D (on ENST00000389232; = p.A3056D on NM_001036.6) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66810030; called by muse, mutect2, varscan2
- SALL1 | c.1736C>G p.P579R | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV51765147; called by muse, mutect2, varscan2
- SAMD9L | c.3902G>A p.R1301K | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1481116213, COSV59085851; called by muse, mutect2, varscan2
- SCAF4 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as COSV54593194; called by muse, mutect2, varscan2
- SCEL | c.1450G>T p.G484* (on ENST00000349847 / NM_144777.3; = p.G464* on NM_003843.4) | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as COSV62994664; called by muse, mutect2, varscan2
- SCN7A | c.1023G>T p.W341C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV101313358; called by mutect2, varscan2
- SCUBE3 | c.2007C>A p.C669* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as COSV51460922; called by muse, mutect2, varscan2
- SDAD1 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.068); catalogued as COSV100668730; called by muse, varscan2
- SDAD1 | c.1188T>A p.N396K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100668731; called by muse, varscan2
- SEC23IP | c.2871A>G p.I957M | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754954332, COSV64833306; called by muse, mutect2, varscan2
- SELE | c.675G>A p.M225I | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV60978025; called by muse, mutect2, varscan2
- SEMA3C | c.335G>T p.C112F | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54856845; called by muse, mutect2, varscan2
- SEMA6D | c.3077C>A p.S1026Y (on ENST00000316364 / NM_153618.2; = p.S964Y on NM_020858.2) | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV60384891; called by muse, mutect2, varscan2
- SEPTIN12 | c.292G>T p.V98F | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV51619233; called by muse, mutect2, varscan2
- SERPINB8 | c.427A>G p.K143E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV54640746; called by muse, mutect2, varscan2
- SERPING1 | c.1358G>T p.G453V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53544557; called by muse, mutect2, varscan2
- SERTAD4 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as rs142929495, COSV65400356; called by muse, mutect2, varscan2
- SETD2 | c.4336G>T p.G1446W | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV57453704; called by muse, mutect2, varscan2
- SEZ6 | c.587T>C p.V196A | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV57985144; called by muse, mutect2, varscan2
- SGK1 | c.1139A>T p.N380I | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.04); catalogued as COSV52815780; called by muse, mutect2, varscan2
- SGTA | c.890G>A p.S297N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV55595790; called by muse, mutect2, varscan2
- SH3RF3 | c.865del p.V289Cfs*69 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | catalogued as COSV100513389; called by mutect2, pindel, varscan2
- SHROOM3 | c.4592C>T p.P1531L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.976); catalogued as COSV56040554; called by muse, mutect2, varscan2
- SLC12A5 | c.265G>T p.A89S (on ENST00000454036 / NM_001134771.2; = p.A66S on NM_020708.5) | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.285); catalogued as COSV54802865; called by muse, mutect2, varscan2
- SLC17A4 | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64957424; called by muse, mutect2, varscan2
- SLC22A3 | c.875C>G p.P292R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99279348; called by muse, mutect2, varscan2
- SLC25A25 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs150336698; called by muse, mutect2, varscan2
- SLC35F1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV64510659; called by muse, mutect2, varscan2
- SLC44A5 | c.1874-1G>T p.X625_splice | Splice Site (SNP) | VAF 31/63 reads (49%) | catalogued as COSV63775596; called by muse, mutect2, varscan2
- SLC7A1 | c.622G>T p.G208* | Nonsense Mutation (SNP) | VAF 9/81 reads (11%) | catalogued as COSV66332022; called by muse, mutect2, varscan2
- SLC9A4 | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as rs755519321, COSV54839886; called by muse, mutect2, varscan2
- SLC9C2 | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1215714350, COSV62949950; called by muse, mutect2, varscan2
- SLFN11 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV57700810; called by muse, mutect2, varscan2
- SLITRK6 | c.2211C>G p.Y737* | Nonsense Mutation (SNP) | VAF 28/204 reads (14%) | catalogued as COSV68389306, COSV68391897; called by muse, mutect2, varscan2
- SMC2 | c.2637A>T p.K879N | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV53965469; called by muse, mutect2, varscan2
- SMCO1 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.104); catalogued as COSV58839752; called by muse, mutect2
- SMOC2 | c.857G>A p.R286K (on ENST00000356284 / NM_001166412.2; = p.R297K on NM_022138.3) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV62444959; called by muse, mutect2, varscan2
- SMYD3 | c.1097A>G p.H366R (on ENST00000490107 / NM_001375962.1; = p.H307R on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs770069752, COSV63629771; called by muse, mutect2, varscan2
- SPATA31D1 | c.3569C>G p.S1190* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as COSV61201934; called by muse, mutect2, varscan2
- SPATA31D1 | c.4340T>A p.V1447E | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as rs776488114, COSV61201942; called by muse, mutect2, varscan2
- SPEN | c.3182C>T p.A1061V | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV65357667, COSV65367964; called by muse, mutect2
- SPHKAP | c.2578C>A p.Q860K | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60896043; called by muse, mutect2, varscan2
- SPTA1 | c.2332C>A p.L778M | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63751430, COSV63753232; called by muse, mutect2, varscan2
- SREBF1 | c.2482G>A p.D828N | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV55399920; called by muse, mutect2, varscan2
- ST8SIA1 | c.48G>T p.M16I | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV53959828; called by muse, mutect2, varscan2
- STK3 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV69227495; called by muse, mutect2, varscan2
- STK31 | c.2638-1G>T p.X880_splice | Splice Site (SNP) | VAF 10/60 reads (17%) | catalogued as COSV63459842; called by muse, varscan2
- SUN1 | c.457G>T p.D153Y (on ENST00000405266 / NM_001367651.1; = p.D103Y on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61777268, COSV61779557; called by muse, mutect2, varscan2
- SYCP1 | c.2599C>A p.Q867K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV65701271; called by muse, mutect2, varscan2
- TAAR6 | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51585023; called by muse, mutect2, varscan2
- TASOR2 | c.2206G>C p.V736L | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV60169878; called by muse, mutect2, varscan2
- TBC1D19 | c.229C>G p.P77A | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.039); catalogued as COSV53522052; called by muse, mutect2, varscan2
- TBX5 | c.793C>A p.Q265K | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV59865952; called by muse, mutect2, varscan2
- TBXT | c.854A>T p.H285L | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV51620350; called by muse, mutect2
- TECRL | c.64A>T p.T22S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV67091018; called by muse, mutect2, varscan2
- TENM3 | c.4309G>C p.E1437Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV69320924; called by muse, mutect2, varscan2
- TEP1 | c.6604G>T p.A2202S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.14); catalogued as COSV53001228; called by muse, mutect2, varscan2
- TEX15 | c.6327G>T p.M2109I (on ENST00000256246; = p.M2492I on NM_001350162.2) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.28); catalogued as COSV56354944; called by muse, mutect2, varscan2
- TFG | c.625A>T p.S209C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53748716, COSV99561244; called by muse, mutect2, varscan2
- THY1 | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV52455530; called by muse, mutect2, varscan2
- TLCD3B | c.445-2A>C p.X149_splice | Splice Site (SNP) | VAF 5/74 reads (7%) | catalogued as COSV54228395; called by muse, mutect2
- TM4SF5 | c.462G>T p.W154C | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54498153; called by muse, mutect2, varscan2
- TMCO3 | c.1070A>G p.Y357C | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.814); catalogued as COSV64809411; called by muse, mutect2
- TMED1 | c.142C>A p.Q48K | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53035551; called by muse, mutect2, varscan2
- TMEM254 | c.106C>G p.Q36E | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV64846145; called by muse, mutect2, varscan2
- TMEM67 | c.737G>T p.C246F | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60045092; called by muse, mutect2, varscan2
- TMIGD2 | c.539A>T p.Q180L | Missense Mutation (SNP) | VAF 15/328 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV56669069; called by muse, mutect2
- TMPRSS11B | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs991403847, COSV60292383, COSV60294358; called by muse, mutect2, varscan2
- TNFRSF10B | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV52394528; called by muse, mutect2, varscan2
- TNFSF18 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs776618991, COSV53440638, COSV53442036; called by muse, mutect2, varscan2
- TNR | c.1034A>T p.E345V | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as COSV54916538; called by muse, mutect2, varscan2
- TOMM34 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 13/133 reads (10%) | catalogued as COSV65689696; called by muse, mutect2
- TPTE2 | c.188T>G p.I63S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs913332064, COSV55029307; called by muse, mutect2, varscan2
- TRHDE | c.2540+1G>T p.X847_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99672375; called by muse, mutect2
- TRPC6 | c.1628C>G p.A543G | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV60251223, COSV60261705; called by muse, mutect2, varscan2
- TSHZ2 | c.2114A>G p.H705R | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61592019; called by muse, mutect2, varscan2
- TSPEAR | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1329340778, COSV59981997; called by muse, varscan2
- TTC17 | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1183718448, COSV50022541; called by muse, mutect2, varscan2
- TTC21A | c.3761C>T p.A1254V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56190155; called by muse, mutect2
- TTC21B | c.3596G>A p.S1199N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV54635902; called by muse, mutect2, varscan2
- TTN | c.41102C>A p.P13701H (on ENST00000591111; = p.P6277H on NM_003319.4) | Missense Mutation (SNP) | VAF 22/80 reads (28%) | PolyPhen possibly damaging (0.487); catalogued as COSV60264876; called by muse, mutect2, varscan2
- TUBA3C | c.933G>T p.K311N | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV67139871, COSV67140134; called by muse, mutect2, varscan2
- TUBGCP3 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.394); catalogued as rs777263605, COSV56189043; called by muse, mutect2, varscan2
- TYR | c.718G>T p.D240Y | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54487064; called by muse, mutect2, varscan2
- UBR5 | c.1237C>G p.R413G | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV99642264; called by muse, mutect2, varscan2
- UTP18 | c.1270G>T p.G424C | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56585493; called by muse, mutect2, varscan2
- UVSSA | c.1378G>C p.A460P | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV66231101; called by muse, mutect2
- VPS13D | c.11018C>T p.A3673V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV50695170; called by muse, mutect2, varscan2
- VPS36 | c.1060A>C p.K354Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV65200220; called by muse, mutect2, varscan2
- WASHC5 | c.512G>C p.R171P | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59201027; called by muse, mutect2, varscan2
- WBP11 | c.321G>C p.L107F | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53765049; called by muse, mutect2
- WDFY3 | c.7593G>T p.E2531D | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV55715157; called by muse, mutect2, varscan2
- XIRP1 | c.998C>A p.P333Q | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV61141740; called by muse, mutect2, varscan2
- XIRP2 | c.36A>C p.E12D (on ENST00000628543; = p.E187D on NM_152381.6) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.452); catalogued as COSV54737722; called by muse, mutect2, varscan2
- XIRP2 | c.7591C>A p.P2531T (on ENST00000628543; = p.P2706T on NM_152381.6) | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV54737737; called by muse, mutect2, varscan2
- XK | c.971G>C p.R324T | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101064798, COSV66120970; called by muse, mutect2, varscan2
- YARS1 | c.1180G>T p.V394L | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV65115477; called by muse, mutect2, varscan2
- YLPM1 | c.5288G>T p.R1763M | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53121594; called by muse, mutect2, varscan2
- YWHAQ | c.221A>G p.K74R | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); catalogued as rs756400871, COSV53004899; called by muse, mutect2, varscan2
- ZAN | c.2240T>C p.I747T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as rs752170895, COSV100768996; called by mutect2, varscan2
- ZCCHC12 | c.945G>T p.R315S | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV59573126; called by muse, mutect2, varscan2
- ZER1 | c.1678G>C p.D560H | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV52569141; called by muse, mutect2, varscan2
- ZFAT | c.1069C>G p.R357G | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.106); catalogued as COSV64748218; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1251G>T p.Q417H | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.115); catalogued as COSV57640468; called by muse, mutect2, varscan2
- ZNF33A | c.939G>C p.L313F (on ENST00000458705 / NM_006974.3; = p.L314F on NM_006954.2) | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.915); catalogued as COSV100275791, COSV56728158; called by muse, mutect2, varscan2
- ZNF429 | c.1768G>C p.E590Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV61919480; called by muse, mutect2, varscan2
- ZNF555 | c.991A>G p.M331V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.94); PolyPhen benign (0.027); catalogued as rs748412136, COSV62074149; called by muse, mutect2, varscan2
- ZNF566 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.616); catalogued as rs144570782, COSV67574349; called by muse, mutect2
- ZNF583 | c.84G>T p.R28S | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV52404873; called by muse, mutect2, varscan2
- ZNF594 | c.1007C>T p.T336I | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as COSV68386340; called by muse, mutect2, varscan2
- ZNF695 | c.213G>T p.R71S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.227); catalogued as COSV60587740; called by muse, mutect2, varscan2
- ZPBP | c.532C>A p.H178N | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV50435964; called by muse, mutect2, varscan2
- ZSCAN30 | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV54353030; called by muse, mutect2, varscan2
- ACACA | c.2631G>C p.Q877H | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2
- AGTR1 | c.837del p.I279Mfs*12 | Frame Shift Del (DEL) | VAF 12/79 reads (15%) | called by mutect2, pindel, varscan2
- BCHE | c.284_312del p.Q95Pfs*11 | Frame Shift Del (DEL) | VAF 7/76 reads (9%) | called by mutect2, pindel
- CAMK2D | c.647del p.D216Vfs*26 | Frame Shift Del (DEL) | VAF 12/97 reads (12%) | called by mutect2, pindel*, varscan2
- CBWD2 | c.764G>A p.S255N | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, varscan2
- DONSON | c.464del p.V155Gfs*23 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- HEATR5B | c.3895del p.A1299Hfs*39 | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | called by mutect2, pindel, varscan2
- HEATR9 | c.410C>G p.P137R | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- HNRNPF | c.711_740del p.T238_S247del | In Frame Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- IGHV3-72 | c.166del p.V56Sfs*30 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | called by mutect2, pindel
- IL13RA2 | c.1032dup p.W345Lfs*21 | Frame Shift Ins (INS) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- LMNTD1 | c.426del p.S143Vfs*8 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | called by mutect2, pindel, varscan2
- MGLL | c.22del p.R8Gfs*58 (on ENST00000398104 / NM_001003794.2; = p.R18Gfs*58 on NM_007283.6) | Frame Shift Del (DEL) | VAF 23/121 reads (19%) | called by mutect2, pindel, varscan2
- MRC1 | c.2558G>T p.R853I | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- NAA10 | c.688_705del p.A230_S235del | In Frame Del (DEL) | VAF 3/38 reads (8%) | called by mutect2, pindel
- NOBOX | c.609del p.K205Sfs*63 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, pindel, varscan2
- OR8G2P | c.390G>T p.L130F | Missense Mutation (SNP) | VAF 79/262 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PHYHIPL | c.592del p.V198Ffs*28 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- PRAG1 | c.2413_2422del p.S805Afs*13 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.66C>A p.D22E | Missense Mutation (SNP) | VAF 81/609 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- PRAMEF19 | c.1010T>C p.L337P | Missense Mutation (SNP) | VAF 18/655 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.17); called by muse, mutect2
- PRDM5 | c.986_999del p.F329Sfs*16 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- PXDNL | c.197del p.P66Qfs*11 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel, varscan2
- SYNRG | c.532G>T p.G178W | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- TUBGCP5 | c.2553A>C p.E851D | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZDBF2 | c.5723_5734del p.D1908_V1911del | In Frame Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- ABCB5 | c.1800G>T p.L600= (on ENST00000404938 / NM_001163941.2; = p.L155= on NM_178559.6) | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV51722236; called by muse, mutect2, varscan2
- ACACB | c.4473C>T p.H1491= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as COSV58148024; called by muse, mutect2, varscan2
- ACACB | c.4833G>A p.V1611= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV58148045; called by muse, mutect2
- ACTA1 | c.144T>C p.G48= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs1265100143, COSV64204209; called by muse, mutect2, varscan2
- ADAR | c.1476C>T p.P492= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as rs1280071964, COSV52721936; called by muse, mutect2
- ADCYAP1R1 | c.714G>T p.V238= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV58447600; called by muse, mutect2, varscan2
- ANO4 | c.1342C>A p.R448= (on ENST00000392977 / NM_001286615.2; = p.R413= on NM_178826.4) | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV54607213, COSV54615480; called by muse, mutect2, varscan2
- ANXA10 | c.762T>C p.Y254= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as rs1232663755, COSV63740687; called by muse, mutect2, varscan2
- AP4M1 | c.1191C>G p.A397= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV57999297; called by muse, mutect2, varscan2
- APCS | c.360A>T p.S120= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV54819402; called by muse, mutect2, varscan2
- ARHGAP5 | c.4174C>T p.L1392= (on ENST00000345122 / NM_001030055.2; = p.L1391= on NM_001173.3) | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV53735640; called by muse, mutect2
- ARMC4 | c.1686T>A p.V562= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV59475570; called by muse, mutect2, varscan2
- ARSG | c.15T>C p.F5= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as rs782662714, COSV71594051; called by muse, mutect2
- ATP12A | c.2079G>T p.L693= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV54524241; called by muse, mutect2, varscan2
- ATP1A1 | c.2022C>G p.T674= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV55194617; called by muse, mutect2, varscan2
- ATP8B1 | c.3144C>T p.F1048= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV52180794; called by muse, mutect2, varscan2
- BAZ2A | c.159G>A p.V53= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1321007157, COSV51644671; called by muse, mutect2, varscan2
- C2CD5 | c.2580G>T p.R860= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV61728197; called by muse, varscan2
- CCN1 | c.888C>G p.V296= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV71704456; called by muse, mutect2, varscan2
- CENPF | c.4935A>G p.L1645= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as rs1160147492, COSV65279601; called by muse, mutect2
- CNTNAP1 | c.1425G>C p.L475= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV52854729; called by muse, mutect2
- COL18A1 | c.2796A>G p.G932= (on ENST00000359759 / NM_130444.3; = p.G697= on NM_030582.4) | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV62707933; called by muse, mutect2, varscan2
- COL19A1 | c.495T>C p.P165= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV59590121; called by muse, mutect2, varscan2
- COL7A1 | c.1293C>T p.I431= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV60403980; called by muse, mutect2, varscan2
- COLEC12 | c.564C>A p.L188= | Silent (SNP) | VAF 64/152 reads (42%) | catalogued as COSV68374359; called by muse, varscan2
- CRB2 | c.1563G>A p.Q521= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV63505880; called by muse, mutect2, varscan2
- CRTAM | c.549C>T p.L183= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as rs760800114, COSV57071720; called by muse, mutect2, varscan2
- CRTC2 | c.546C>T p.P182= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV57845942; called by muse, mutect2
- CXorf66 | c.816A>G p.K272= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV65169856; called by muse, mutect2, varscan2
- CYP11B2 | c.1395C>T p.H465= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV59998083; called by muse, mutect2, varscan2
- DCAF12L2 | c.306G>C p.A102= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV63582487, COSV63584428; called by muse, mutect2, varscan2
- DKKL1 | c.708C>T p.L236= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV55562715, COSV55563999; called by muse, mutect2, varscan2
- DOCK4 | c.1314G>A p.L438= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV70326205; called by muse, mutect2, varscan2
- DPYSL4 | c.1560G>T p.A520= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV53846584; called by muse, mutect2, varscan2
- DSCAM | c.4083C>A p.A1361= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV68037525; called by muse, mutect2, varscan2
- EDRF1 | c.2283T>C p.N761= (on ENST00000356792 / NM_001202438.2; = p.N727= on NM_015608.2) | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as rs1158261439, COSV61765632, COSV61766505; called by muse, mutect2, varscan2
- EP300 | c.6783G>A p.Q2261= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV54329747; called by muse, mutect2, varscan2
- EXOC3L1 | c.793C>T p.L265= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV52048584; called by muse, mutect2, varscan2
- FAH | c.678T>C p.F226= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV55723937; called by muse, mutect2
- FAT4 | c.1650G>A p.L550= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV67901771; called by mutect2, varscan2
- FICD | c.60C>A p.V20= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV64202367; called by muse, mutect2, varscan2
- FREM2 | c.6594C>G p.P2198= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV54854403; called by muse, mutect2, varscan2
- FRYL | c.292C>A p.R98= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV51942336, COSV51963863; called by muse, mutect2, varscan2
- GOLGA4 | c.5991G>A p.L1997= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV100729148; called by muse, mutect2, varscan2
- GOLGB1 | c.1194A>G p.L398= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV61471833; called by muse, mutect2, varscan2
- GPR158 | c.1707C>T p.I569= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV66284158, COSV66284968; called by muse, mutect2, varscan2
- GRM6 | c.1266C>A p.L422= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV51443955; called by muse, mutect2, varscan2
- HEXD | c.402G>A p.L134= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs1449132265, COSV60066337; called by muse, mutect2, varscan2
- HOXD3 | c.234C>A p.A78= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV50885954; called by muse, mutect2, varscan2
- HSPD1 | c.153G>A p.V51= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV52100356; called by muse, varscan2
- HTR3E | c.906C>A p.T302= (on ENST00000415389 / NM_001256613.1; = p.T317= on NM_182589.2) | Silent (SNP) | VAF 21/167 reads (13%) | catalogued as COSV58949203; called by muse, mutect2, varscan2
- IGDCC3 | c.2118C>A p.G706= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV60080645; called by muse, mutect2, varscan2
- IGSF3 | c.1422C>T p.S474= (on ENST00000369486 / NM_001007237.3; = p.S494= on NM_001542.4) | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV59599323; called by muse, mutect2
- ITGA7 | c.1086C>T p.S362= (on ENST00000555728; = p.S318= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs146864775; ClinVar: likely benign; called by muse, mutect2, varscan2
- KAT6B | c.417C>A p.L139= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as COSV54755684; called by muse, mutect2, varscan2
- KCNJ1 | c.1102A>C p.R368= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV60662943; called by muse, mutect2, varscan2
- KCNK2 | c.1074C>T p.A358= (on ENST00000444842 / NM_001017425.3; = p.A343= on NM_014217.4) | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV67209703, COSV67209709, COSV67210933; called by muse, mutect2, varscan2
- KCNN3 | c.1971C>A p.I657= (on ENST00000618040 / NM_001204087.1; = p.I642= on NM_002249.6) | Silent (SNP) | VAF 15/251 reads (6%) | catalogued as COSV55227987; called by muse, mutect2
- KLHL1 | c.387G>T p.V129= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV100918105; called by muse, mutect2, varscan2
- KLHL24 | c.1449A>T p.L483= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV54429083; called by muse, varscan2
- KMT2A | c.7494C>G p.P2498= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV63293204; called by muse, mutect2, varscan2
- KRTAP11-1 | c.405A>T p.G135= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV60095553; called by muse, mutect2, varscan2
- KRTAP11-1 | c.207C>A p.T69= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV60095566; called by muse, mutect2, varscan2
- LAMA4 | c.4062C>T p.Y1354= (on ENST00000230538 / NM_001105206.3; = p.Y1347= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV57905869; called by muse, mutect2, varscan2
- LMOD2 | c.768A>T p.A256= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV71755891; called by muse, mutect2, varscan2
- LRRC42 | c.352C>T p.L118= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV59962078; called by muse, mutect2, varscan2
- MAGEA3 | c.738C>G p.L246= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV100939101, COSV64756593; called by muse, mutect2, varscan2
- MAGEC1 | c.1392G>A p.E464= | Silent (SNP) | VAF 43/109 reads (39%) | catalogued as COSV53582401; called by muse, mutect2, varscan2
- MAN2A1 | c.2811T>G p.A937= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV54859328; called by muse, mutect2, varscan2
- MSRB3 | c.294C>A p.T98= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV57599001; called by muse, varscan2
- MTTP | c.1290C>A p.I430= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as COSV55510389; called by muse, mutect2, varscan2
- MUC16 | c.2496A>T p.S832= | Silent (SNP) | VAF 77/159 reads (48%) | catalogued as COSV67497822; called by muse, mutect2, varscan2
- MUC5B | c.12954C>A p.S4318= | Silent (SNP) | VAF 41/134 reads (31%) | catalogued as COSV101500731, COSV71591601; called by muse, mutect2, varscan2
- MYH6 | c.3468C>G p.G1156= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, varscan2
- NCAM2 | c.1755C>A p.I585= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs752975006, COSV53077944, COSV53106614; called by muse, mutect2, varscan2
- NLRP6 | c.2256G>A p.L752= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs1432486731, COSV56462237; called by muse, mutect2, varscan2
- NNMT | c.765G>T p.L255= | Silent (SNP) | VAF 46/135 reads (34%) | catalogued as COSV55475170; called by muse, mutect2, varscan2
- NRF1 | c.978A>T p.A326= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV56217313; called by muse, mutect2, varscan2
- NSD1 | c.5856G>T p.R1952= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV61785858; called by muse, mutect2, varscan2
- NSD2 | c.2310C>T p.S770= | Silent (SNP) | VAF 12/170 reads (7%) | catalogued as COSV56397310; called by muse, mutect2
- NTAQ1 | c.501G>A p.E167= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV54876285; called by muse, mutect2, varscan2
- OPN4 | c.186G>T p.T62= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as rs143739960, COSV99618685; called by muse, mutect2, varscan2
- OR10Z1 | c.390C>T p.L130= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV63525987, COSV63526723; called by muse, mutect2, varscan2
- OR2L13 | c.651T>C p.C217= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV63562228; called by muse, mutect2, varscan2
- OR2T4 | c.825C>A p.S275= | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as COSV63543282, COSV63545233; called by muse, mutect2, varscan2
- OR4D11 | c.111G>T p.T37= | Silent (SNP) | VAF 18/139 reads (13%) | catalogued as COSV57587347; called by muse, varscan2
- OR8J1 | c.303G>T p.L101= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as COSV57319791; called by muse, varscan2
- OTX1 | c.300G>T p.G100= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV56996393; called by muse, mutect2, varscan2
- PASK | c.3135A>G p.K1045= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV52151018, COSV52161781; called by muse, mutect2, varscan2
- PATL1 | c.2259G>C p.R753= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV100275223; called by muse, mutect2
- PAX5 | c.939C>T p.P313= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1563927570, COSV63907230; called by muse, varscan2
- PCDHA5 | c.402A>G p.R134= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs1554128487, COSV65358569; called by muse, mutect2, varscan2
- PDE4DIP | c.3504G>C p.V1168= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV57731945; called by mutect2, varscan2
- PEG3 | c.2385G>T p.G795= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as COSV55649437; called by muse, mutect2, varscan2
- PKHD1 | c.10692C>A p.A3564= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV64401459; called by muse, mutect2, varscan2
- PLEKHA6 | c.1989G>A p.R663= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs747314243, COSV55340953; called by mutect2, varscan2
- PLEKHH2 | c.1854G>T p.L618= | Silent (SNP) | VAF 61/155 reads (39%) | catalogued as COSV56761887; called by muse, mutect2, varscan2
- PPP2R5B | c.756G>A p.V252= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV51213802; called by muse, mutect2, varscan2
- PRKN | c.1065C>A p.G355= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV58283884; called by muse, mutect2, varscan2
- PTPRB | c.2259G>T p.V753= | Silent (SNP) | VAF 19/161 reads (12%) | catalogued as COSV54255302; called by muse, mutect2, varscan2
- RAI1 | c.3678G>C p.S1226= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV55399901; called by muse, mutect2, varscan2
- RAP2B | c.72G>A p.V24= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV60257050; called by muse, mutect2, varscan2
- RHAG | c.408G>A p.T136= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs138437733; called by muse, mutect2, varscan2
- RIOX1 | c.1113G>C p.L371= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV58374936; called by muse, mutect2, varscan2
- RNASEH2B | c.789T>C p.T263= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV60748036; called by muse, mutect2, varscan2
- RNF152 | c.9G>T p.T3= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV57186704, COSV57188488; called by muse, mutect2, varscan2
- RPL8 | c.114C>T p.H38= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs201586885; called by muse, mutect2, varscan2
- RPP38 | c.315G>C p.T105= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV65383422; called by muse, mutect2, varscan2
- RPRD2 | c.3018G>C p.T1006= | Silent (SNP) | VAF 100/289 reads (35%) | catalogued as COSV64823584; called by muse, mutect2, varscan2
- RYR2 | c.8266T>C p.L2756= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV63718055; called by muse, mutect2, varscan2
- RYR2 | c.14424T>C p.D4808= | Silent (SNP) | VAF 41/172 reads (24%) | catalogued as COSV63718062; called by muse, mutect2, varscan2
- SHLD2 | c.1011A>C p.T337= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV100079500; called by muse, mutect2, varscan2
- SIPA1L1 | c.225G>T p.G75= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV62174183; called by muse, mutect2, varscan2
- SIPA1L2 | c.4911C>T p.G1637= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV53401199; called by muse, mutect2, varscan2
- SLC1A6 | c.726G>A p.R242= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV55674640; called by muse, mutect2, varscan2
- SLC22A3 | c.876C>T p.P292= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV99279350; called by muse, mutect2, varscan2
- SLC2A2 | c.54G>T p.V18= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as COSV58588851; called by muse, mutect2
- SLC38A6 | c.1002A>G p.L334= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs1375509276, COSV50786614; called by mutect2, varscan2
- SLC4A4 | c.672G>T p.L224= (on ENST00000264485 / NM_001098484.3; = p.L180= on NM_003759.4) | Silent (SNP) | VAF 29/181 reads (16%) | catalogued as COSV52640037; called by muse, mutect2, varscan2
- SLC6A3 | c.855C>T p.V285= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as COSV54370100; called by muse, mutect2, varscan2
- SLIT3 | c.1431G>A p.Q477= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV60635145; called by muse, mutect2, varscan2
- SLITRK1 | c.1752G>A p.R584= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs569159908, COSV65677530; called by muse, mutect2, varscan2
- SORL1 | c.972C>T p.V324= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV52763595; called by muse, mutect2, varscan2
- SPTA1 | c.2442C>T p.P814= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV63750714, COSV63760552; called by muse, mutect2, varscan2
- STAT5A | c.2034C>T p.V678= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV61808686; called by muse, mutect2, varscan2
- TAF6L | c.855C>G p.L285= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs775271555, COSV53671228; called by muse, mutect2, varscan2
- TEP1 | c.1599G>C p.L533= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV53001240; called by muse, mutect2, varscan2
- TEX14 | c.1335C>T p.I445= (on ENST00000240361 / NM_001201457.2; = p.I439= on NM_031272.5) | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV53624930; called by muse, mutect2, varscan2
- TFDP2 | c.798G>T p.P266= (on ENST00000489671 / NM_001178139.2; = p.P206= on NM_006286.5) | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV57712083; called by muse, mutect2, varscan2
- THSD1 | c.1635G>A p.L545= | Silent (SNP) | VAF 52/189 reads (28%) | catalogued as COSV51627075; called by muse, mutect2, varscan2
- TRIM3 | c.924G>A p.S308= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs1176284010, COSV61985856; called by muse, mutect2, varscan2
- TROAP | c.2235C>T p.G745= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV57746172; called by muse, mutect2, varscan2
- TRPM4 | c.651G>T p.P217= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs758473371, COSV53269373; called by muse, mutect2, varscan2
- UBASH3B | c.255C>T p.P85= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV52494628; called by muse, mutect2, varscan2
- UBE2C | c.387G>A p.R129= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs747624674, COSV54754456, COSV54755647; called by muse, mutect2, varscan2
- UROC1 | c.1527A>C p.A509= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV52039979; called by muse, mutect2
- VRTN | c.139C>A p.R47= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV56444039, COSV56444293; called by mutect2, varscan2
- WDR33 | c.3445A>C p.R1149= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as COSV59256163; called by muse, mutect2, varscan2
- ZMAT5 | c.489G>A p.L163= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV53364280; called by muse, mutect2, varscan2
- ZNF257 | c.1147C>A p.R383= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs559375603, COSV71311201, COSV71312189; called by muse, mutect2, varscan2
- ZNF518B | c.834A>G p.L278= | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as COSV58725051; called by muse, mutect2, varscan2
- ZNF680 | c.1272T>C p.H424= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV59018623; called by mutect2, varscan2
- ZNF680 | c.375T>C p.S125= | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as COSV59018631; called by muse, mutect2
- AGXT | c.-2C>A | 5'UTR (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100280350; called by muse, varscan2
- AL353804.4 | chrX:73824863 C>A | 5'Flank (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851699 G>A | 3'Flank (SNP) | VAF 5/22 reads (23%) | catalogued as rs766959904; called by muse, mutect2, varscan2
- AMDHD2 | c.*1042G>C | 3'UTR (SNP) | VAF 20/78 reads (26%) | catalogued as COSV53552633; called by muse, mutect2, varscan2
- ANKRD13D | c.*1536G>A | 3'UTR (SNP) | VAF 13/39 reads (33%) | catalogued as rs772851895, COSV57387007; called by muse, mutect2, varscan2
- CNNM2 | c.1621+7257G>A | Intron (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100881759; called by muse, mutect2, varscan2
- DDX39B | c.616+107A>C | Intron (SNP) | VAF 22/52 reads (42%) | catalogued as COSV100795189, COSV100795275; called by muse, mutect2, varscan2
- DEFB119 | c.61+1292G>C | Intron (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100191181; called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457836 C>A | 5'Flank (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- LINC00303 | n.251C>T | RNA (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- OBSCN | c.11660-1179G>A | Intron (SNP) | VAF 10/72 reads (14%) | catalogued as COSV99483956; called by muse, mutect2, varscan2
- PKD1L1 | c.*1G>C | 3'UTR (SNP) | VAF 38/136 reads (28%) | catalogued as COSV99221295; called by muse, mutect2, varscan2
- TBC1D32 | c.2571-9449G>C | Intron (SNP) | VAF 12/36 reads (33%) | catalogued as COSV51543155; called by muse, varscan2
- TOGARAM1 | c.-1C>G | 5'UTR (SNP) | VAF 3/41 reads (7%) | catalogued as COSV100753284; called by muse, mutect2
- ZNF783 | c.802+3046G>C | Intron (SNP) | VAF 21/67 reads (31%) | catalogued as rs750167648, COSV100954296; called by muse, mutect2, varscan2
